Somatic mutation profile of tumor specimen MP2PRT-PAVEET-TMP1-A (aliquot MP2PRT-PAVEET-TMP1-A-1-0-D-A820-36) from MP2PRT case MP2PRT-PAVEET, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.7 years (994 days).
Specimen MP2PRT-PAVEET-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 86966a8e-fd82-4bb2-a814-4b2bd9a929cc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVEET-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVEET-NB1-A-1-0-D-A820-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/70c6aa5a-adf3-4134-9d39-8f5ecffc4255

The open-access MAF lists 9 somatic variants for this specimen: 6 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 6, Silent 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL1A2 | c.2869G>A p.V957I | Missense Mutation (SNP) | VAF 116/419 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as rs150867327; called by muse, mutect2, varscan2
- CUL9 | c.5156G>A p.C1719Y | Missense Mutation (SNP) | VAF 23/503 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs753073811; called by muse, mutect2
- FAT2 | c.4363G>A p.V1455I | Missense Mutation (SNP) | VAF 105/403 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.097); catalogued as rs759750416; called by muse, mutect2, varscan2
- RNF224 | c.463G>A p.E155K | Missense Mutation (SNP) | VAF 71/280 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.171); catalogued as rs761579574; called by muse, mutect2, varscan2
- SCN10A | c.3793G>A p.E1265K | Missense Mutation (SNP) | VAF 78/277 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.509); catalogued as COSV101479348, COSV101479410; called by muse, mutect2, varscan2
- ST6GALNAC6 | c.95G>T p.R32L | Missense Mutation (SNP) | VAF 82/377 reads (22%) | PolyPhen benign (0.41); catalogued as rs1422661681, COSV52535627; called by muse, mutect2, varscan2
- AL592490.1 | c.2001C>T p.D667= | Silent (SNP) | VAF 79/303 reads (26%) | catalogued as rs535309463, COSV69427096; called by muse, mutect2, varscan2
- CARM1 | c.1623G>A p.T541= | Silent (SNP) | VAF 85/342 reads (25%) | catalogued as rs776770174, COSV53402755, COSV53404174; called by muse, mutect2, varscan2
- IGLV4-69 | c.359del p.*120= | Silent (DEL) | VAF 33/141 reads (23%) | called by pindel*, varscan2
